Somatic mutation profile of tumor specimen TCGA-D3-A2J8-06A (aliquot TCGA-D3-A2J8-06A-11D-A196-08) from TCGA case TCGA-D3-A2J8, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 53.0 years (19,363 days).
Specimen TCGA-D3-A2J8-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35cb0a18-bb62-4738-9625-0ab7c6a34361.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A2J8-10A (Blood Derived Normal), aliquot TCGA-D3-A2J8-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6cf01ff-74e9-4ada-8db5-84fa1afbcd3e

The open-access MAF lists 609 somatic variants for this specimen: 386 protein-altering or splice-affecting, 210 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 357, Silent 210, Nonsense Mutation 20, Intron 5, Splice Region 5, Splice Site 3, RNA 3, 3'Flank 2, 3'UTR 1, 5'UTR 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH9 | c.7102G>A p.E2368K | Missense Mutation (SNP) | VAF 12/94 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as rs140313224, COSV52337194; called by mutect2, varscan2
- EPHA7 | c.1967G>A p.G656E | Missense Mutation (SNP) | VAF 8/118 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65180770; called by muse, mutect2
- HUWE1 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557036757, COSV53341725; ClinVar: likely pathogenic; called by mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 38/181 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.313T>G p.C105G | Missense Mutation (SNP) | VAF 12/77 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1303165645, COSV64291447, COSV64294430, COSV64295504, COSV64310426; called by muse, mutect2, varscan2
- ABCB7 | c.472C>T p.P158S (on ENST00000373394 / NM_001271696.3; = p.P159S on NM_004299.6) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53719129; called by muse, mutect2, varscan2
- ABCC11 | c.1517G>A p.G506E | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0.013); catalogued as COSV62322476; called by muse, mutect2, varscan2
- ABCC3 | c.2677G>A p.D893N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.076); catalogued as COSV53319670; called by mutect2, varscan2
- ABCG8 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 55/554 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs769649113, COSV55392165; called by muse, mutect2, varscan2
- ACMSD | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267598885, COSV51606002, COSV51609903; called by mutect2, varscan2
- ACOT12 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs564306951, COSV56892647, COSV56894194; called by mutect2, varscan2
- ADAM28 | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867843641, COSV56098311; called by mutect2, varscan2
- ADAMTS19 | c.2419G>A p.G807R | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1230320586, COSV50740569; called by muse, mutect2
- ADAMTS20 | c.4480C>T p.Q1494* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV67129810; called by mutect2, varscan2
- ADAMTS9 | c.3608G>A p.R1203Q | Missense Mutation (SNP) | VAF 27/472 reads (6%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.642); catalogued as rs1278897392, COSV55778664; called by muse, mutect2
- ADGRV1 | c.5734G>A p.D1912N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV67979546; called by mutect2, varscan2
- AEBP2 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); catalogued as COSV56862844, COSV56863268; called by muse, mutect2
- AGTR1 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62557761; called by muse, mutect2, varscan2
- AKAP9 | c.9263T>A p.L3088* (on ENST00000359028; = p.L3064* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/266 reads (8%) | catalogued as COSV62343257; called by muse, mutect2
- AL645922.1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 81/786 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV54960210; called by muse, mutect2, varscan2
- ANK2 | c.3413G>A p.R1138Q | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1353812954, COSV52155192; ClinVar: uncertain significance; called by mutect2, varscan2
- ANK3 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs200194900, COSV55066579, COSV99778479; called by mutect2, varscan2
- ANKEF1 | c.2023A>T p.K675* | Nonsense Mutation (SNP) | VAF 10/81 reads (12%) | catalogued as COSV65692244; called by mutect2, varscan2
- ANO3 | c.1238G>A p.G413D | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756369802, COSV56787335; called by mutect2, varscan2
- ANO3 | c.2086G>A p.G696S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.732); catalogued as COSV56787341; called by muse, mutect2, varscan2
- AOX1 | c.1955C>T p.S652F | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV65980989; called by muse, mutect2, varscan2
- APBB1IP | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV63302092; called by muse, mutect2
- APBB1IP | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66131368; called by muse, mutect2, varscan2
- APBB2 | c.1513C>T p.R505C (on ENST00000295974 / NM_001166050.2; = p.R506C on NM_004307.2) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770349315, COSV55950510; called by mutect2, varscan2
- ARAP1 | c.1754C>T p.S585F (on ENST00000393609 / NM_001040118.2; = p.S340F on NM_015242.4) | Missense Mutation (SNP) | VAF 44/522 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760718552, COSV61990609; called by muse, mutect2
- ARHGAP30 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.19); catalogued as COSV100920330, COSV63515847; called by muse, mutect2, varscan2
- ARHGAP33 | c.2978C>T p.A993V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV50121421; called by muse, mutect2, varscan2
- ARMC9 | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV63020224; called by muse, mutect2, varscan2
- ASTN1 | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 114/409 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752367629, COSV56060646; called by muse, mutect2, varscan2
- ASXL3 | c.5537G>A p.G1846E | Missense Mutation (SNP) | VAF 40/353 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as COSV52462958; called by muse, mutect2, varscan2
- ATP11A | c.2687C>T p.P896L | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV52109628; called by muse, mutect2, varscan2
- ATP8A2 | c.1116T>A p.N372K | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99680222; called by muse, mutect2
- ATP8A2 | c.1117C>T p.L373F | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99680224; called by muse, mutect2
- B4GALNT3 | c.2522C>T p.S841F | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56751532; called by muse, mutect2, varscan2
- BCO1 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV50728908; called by muse, mutect2, varscan2
- BPI | c.451G>A p.G151S (on ENST00000262865; = p.G147S on NM_001725.3) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.638); catalogued as rs990022566, COSV53405075; called by muse, mutect2, varscan2
- BRINP1 | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV56297031; called by muse, mutect2
- BRINP3 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.086); catalogued as COSV66515887; called by muse, mutect2, varscan2
- BSN | c.7673C>T p.S2558F | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56515817; called by mutect2, varscan2
- BTBD11 | c.2168G>A p.G723E (on ENST00000280758 / NM_001018072.2; = p.G260E on NM_001017523.2) | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55021625; called by muse, mutect2, varscan2
- C4BPB | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 10/100 reads (10%) | catalogued as COSV54691221; called by mutect2, varscan2
- C8A | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as rs1043425650, COSV63483624; called by muse, mutect2, varscan2
- CACNA1C | c.4200G>C p.Q1400H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV59708918; called by muse, mutect2, varscan2
- CACNA1E | c.2770C>T p.R924C | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs757890592, COSV62383300; called by mutect2, varscan2
- CACNA1E | c.4054G>A p.E1352K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as rs868114151, COSV62389379; called by mutect2, varscan2
- CACNA1F | c.5480G>A p.R1827Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs372426153, COSV59903951; called by muse, mutect2, varscan2
- CACNA1H | c.4052G>A p.G1351E | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61987543; called by muse, mutect2
- CACNA1S | c.5219C>T p.P1740L | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.058); catalogued as rs987296380, COSV62938493; called by muse, mutect2, varscan2
- CAMSAP1 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100409608; called by muse, mutect2
- CCDC105 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1319244844, COSV52963676; called by muse, mutect2, varscan2
- CCDC7 | c.3466A>G p.T1156A | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); catalogued as COSV56540161; called by muse, mutect2, varscan2
- CCDC7 | c.4100C>T p.P1367L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs367590936; called by muse, mutect2
- CCR2 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV52748232, COSV52749827; called by muse, mutect2, varscan2
- CCT5 | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54723549; called by muse, mutect2, varscan2
- CD1B | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV63804063; called by mutect2, varscan2
- CDH10 | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV52569365; called by mutect2, varscan2
- CDH16 | c.2168-1G>A p.X723_splice | Splice Site (SNP) | VAF 5/56 reads (9%) | catalogued as rs1307777934, COSV55335988; called by muse, mutect2
- CDH6 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as rs202247793, COSV54065357; called by mutect2, varscan2
- CEACAM20 | c.1614G>A p.T538= | Splice Region (SNP) | VAF 34/311 reads (11%) | catalogued as rs762179860, COSV57601271; called by mutect2, varscan2
- CECR2 | c.3137C>T p.P1046L (on ENST00000342247 / NM_001290047.2; = p.P862L on NM_001290046.1) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.012); catalogued as COSV52839268; called by muse, mutect2, varscan2
- CEP192 | c.3976T>A p.S1326T | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV58062458; called by muse, mutect2, varscan2
- CFAP43 | c.4506G>A p.W1502* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as rs1327299547, COSV63852711; called by muse, mutect2, varscan2
- CFHR5 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as rs779001368, COSV56817744; called by mutect2, varscan2
- CHD5 | c.1676G>A p.G559E | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs759443731, COSV52412063; called by muse, varscan2
- CHD6 | c.4474G>A p.D1492N | Missense Mutation (SNP) | VAF 29/292 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748610405, COSV64689600; called by muse, mutect2
- CLCN1 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV58368950; called by muse, mutect2, varscan2
- CLCN1 | c.2753G>A p.G918E | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV58368960, COSV58370870; called by mutect2, varscan2
- CLCN3 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0.049); catalogued as COSV61626795; called by muse, mutect2, varscan2
- CLDN16 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs761824865, COSV53227483; called by muse, varscan2
- CLK2 | c.1201C>T p.P401S (on ENST00000368361 / NM_001294339.2; = p.P400S on NM_003993.4) | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56944531, COSV56946941; called by muse, mutect2
- CNBD2 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV62586723; called by muse, mutect2
- CNGB3 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs772140410, COSV60687848; called by muse, mutect2, varscan2
- CNTNAP2 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.189); catalogued as rs777884519, CM1313256, COSV62148925; called by mutect2, varscan2
- CNTNAP5 | c.1493C>T p.T498I | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV70481398; called by mutect2, varscan2
- COL14A1 | c.5165G>A p.G1722E | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV52851359; called by muse, mutect2, varscan2
- COL4A5 | c.4043G>A p.G1348E | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CP962985, COSV60359408; called by muse, mutect2, varscan2
- COL9A2 | c.792+1G>A p.X264_splice | Splice Site (SNP) | VAF 20/136 reads (15%) | catalogued as COSV65607362; called by muse, mutect2, varscan2
- COP1 | c.1419C>T p.I473= | Splice Region (SNP) | VAF 13/155 reads (8%) | catalogued as COSV58165522; called by muse, mutect2
- CPA5 | c.548G>A p.G183D | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV62569282; called by muse, mutect2, varscan2
- CPT1B | c.1273T>G p.S425A | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100376945, COSV56416058; called by muse, mutect2
- CSTF2 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as COSV63376085; called by mutect2, varscan2
- CTCFL | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54772942, COSV54773288; called by muse, mutect2, varscan2
- CYP2C19 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs770375701, COSV64907081; called by muse, mutect2, varscan2
- CYP4X1 | c.1468C>T p.H490Y | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV64150344; called by muse, mutect2, varscan2
- DAB1 | c.1162C>T p.P388S (on ENST00000371231; = p.P355S on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.06); catalogued as COSV100976722, COSV64691995; called by muse, mutect2, varscan2
- DMBT1 | c.6197G>A p.G2066E (on ENST00000338354 / NM_001377530.1; = p.G1309E on NM_004406.3) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100354835, COSV57539354, COSV57540192; called by muse, mutect2, varscan2
- DMXL1 | c.8873C>T p.S2958F | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV60708955; called by muse, mutect2, varscan2
- DNAH11 | c.8959C>T p.P2987S | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60950519; called by muse, mutect2
- DNAH2 | c.4057G>A p.E1353K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs372974924, COSV66718453; called by mutect2, varscan2
- DNAH2 | c.6005T>C p.V2002A | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV66718455; called by muse, mutect2
- DNAH3 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99765180; called by muse, mutect2
- DNAH7 | c.10799G>A p.W3600* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as rs1267529760, COSV56759341; called by muse, mutect2, varscan2
- DNAH8 | c.1020A>T p.K340N | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV59437490, COSV59439573; called by muse, mutect2
- DNAH8 | c.12259C>T p.Q4087* | Nonsense Mutation (SNP) | VAF 12/109 reads (11%) | catalogued as COSV59422239; called by muse, mutect2, varscan2
- DNTT | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV64522576; called by muse, mutect2, varscan2
- DPP6 | c.958G>A p.D320N (on ENST00000377770 / NM_001364500.2; = p.D258N on NM_001936.5) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.978); catalogued as COSV59606371; called by mutect2, varscan2
- DRC7 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV61054060; called by mutect2, varscan2
- ECM2 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV60739977; called by muse, mutect2, varscan2
- ECSCR | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.232); catalogued as COSV101579658; called by muse, mutect2, varscan2
- EFCAB6 | c.2602C>T p.R868* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as rs369031858; called by mutect2, varscan2
- EFHB | c.278G>A p.S93N | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as COSV55546857; called by muse, mutect2
- ELAVL2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.233); catalogued as COSV56360145; called by mutect2, varscan2
- ELMOD2 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV60270275; called by muse, mutect2
- ENTPD3 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781168719, COSV57194023; called by muse, mutect2
- ERBB4 | c.3425G>A p.R1142Q | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.223); catalogued as rs3748961, COSV61478678; called by mutect2, varscan2
- ERC1 | c.2221G>A p.E741K (on ENST00000360905 / NM_178040.4; = p.E713K on NM_178039.4) | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV61693542; called by muse, mutect2, varscan2
- FASTKD5 | c.2284T>C p.S762P | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV53905362; called by muse, mutect2, varscan2
- FAT3 | c.4504G>A p.D1502N | Missense Mutation (SNP) | VAF 52/387 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs780293516, COSV53096910, COSV53158864; called by muse, mutect2, varscan2
- FBXL20 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.217); catalogued as COSV99233767, COSV99234610; called by muse, mutect2
- FIBIN | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as rs1234369679, COSV59412407, COSV59412707; called by muse, mutect2, varscan2
- FKBP11 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs753598888, COSV56739394; called by mutect2, varscan2
- FLII | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.488); catalogued as COSV58944413; called by muse, mutect2
- FPR2 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.651); catalogued as COSV60672050; called by muse, mutect2
- FREM2 | c.4658C>T p.P1553L | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV54834238; called by muse, mutect2, varscan2
- FRS3 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as COSV52484599; called by muse, mutect2, varscan2
- FSD1 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.374); catalogued as COSV99696614; called by muse, mutect2, varscan2
- FYN | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57612844; called by muse, mutect2
- GABRA3 | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1391589124, COSV64797356; called by muse, mutect2, varscan2
- GIMAP4 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55431866; called by muse, mutect2, varscan2
- GJA5 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV54785854; called by muse, mutect2
- GPR141 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759565313, COSV57731278, COSV57732248; called by mutect2, varscan2
- GPR50 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as COSV54437487; called by muse, varscan2
- GRIN2B | c.4099C>T p.P1367S | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV101662926; called by mutect2, varscan2
- GUCY1A2 | c.2135C>T p.S712L | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.574); catalogued as rs1383258563, COSV56477773; called by muse, mutect2, varscan2
- H3-5 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV61187041; called by muse, mutect2
- HECW2 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.978); catalogued as rs764980123, COSV53655313, COSV53671757; called by mutect2, varscan2
- HHIPL2 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 128/949 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58564422; called by muse, mutect2, varscan2
- HHIPL2 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 107/845 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV58564235; called by muse, mutect2, varscan2
- HHLA2 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV63316669, COSV63316866; called by muse, mutect2, varscan2
- HIVEP1 | c.5831G>A p.W1944* | Nonsense Mutation (SNP) | VAF 15/108 reads (14%) | catalogued as COSV101046012, COSV65100347; called by muse, mutect2, varscan2
- HLA-DQA2 | c.760C>T p.L254F | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV66565035; called by muse, mutect2
- HMCN1 | c.4447C>T p.P1483S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54891094; called by muse, mutect2, varscan2
- HNRNPCL1 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.36); catalogued as COSV58610864; called by muse, mutect2, varscan2
- HSD17B2 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.206); catalogued as COSV52275307; called by muse, varscan2
- HTR3B | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV52743838; called by muse, mutect2, varscan2
- IFT122 | c.1978G>A p.E660K (on ENST00000348417 / NM_052989.3; = p.E601K on NM_018262.4) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.257); catalogued as COSV56201941; called by muse, mutect2, varscan2
- IGKV2D-29 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV101534361; called by muse, mutect2, varscan2
- IGLV5-52 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as rs572994523; called by mutect2, varscan2
- IGLV8-61 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.928); catalogued as COSV66502620; called by muse, mutect2, varscan2
- IMPG1 | c.1633C>T p.H545Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.177); catalogued as COSV64054040; called by mutect2, varscan2
- INO80 | c.2597C>T p.P866L | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.981); catalogued as COSV62737312; called by muse, mutect2, varscan2
- INSRR | c.2578G>A p.A860T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV100947172; called by muse, mutect2, varscan2
- INSRR | c.2577G>A p.E859= | Splice Region (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100947173; called by muse, mutect2, varscan2
- IREB2 | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777437554, COSV51921758; called by mutect2, varscan2
- IRX5 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV58058786; called by mutect2, varscan2
- ITGA5 | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 24/205 reads (12%) | catalogued as rs1414929192, COSV53215620; called by muse, mutect2, varscan2
- ITK | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 40/478 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781475918, COSV70061653; called by muse, mutect2
- ITPRID1 | c.3106G>A p.G1036R | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs1288514373, COSV60080090; called by muse, mutect2, varscan2
- IZUMO1 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV55803874; called by mutect2, varscan2
- JAG1 | c.1916G>A p.R639K | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs1313242645, COSV54755615; called by muse, mutect2
- JHY | c.479T>C p.L160S | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as COSV56218784; called by muse, mutect2, varscan2
- KAT7 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52013977; called by muse, mutect2
- KCND2 | c.1571G>A p.G524E | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.057); catalogued as COSV58575693; called by muse, mutect2, varscan2
- KCNH7 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.101); catalogued as COSV59793012; called by mutect2, varscan2
- KCNK9 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as rs756601239, COSV57279846; called by mutect2, varscan2
- KCNV1 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.367); catalogued as rs1208332406, COSV52085557, COSV52087748; called by muse, mutect2, varscan2
- KDM5D | c.1762C>T p.P588S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV58736265; called by muse, mutect2, varscan2
- KIF18B | c.1337C>T p.S446F (on ENST00000593135 / NM_001265577.2; = p.S458F on NM_001264573.2) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.218); catalogued as COSV59271513; called by muse, mutect2, varscan2
- KIF20B | c.3613C>T p.Q1205* (on ENST00000371728 / NM_001284259.2; = p.Q1165* on NM_016195.4) | Nonsense Mutation (SNP) | VAF 16/75 reads (21%) | catalogued as COSV53305381; called by muse, mutect2, varscan2
- KIF5A | c.2936G>A p.G979E | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.015); catalogued as rs1156869738, CD1312767, COSV54053491; called by muse, mutect2, varscan2
- KIRREL2 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); catalogued as COSV52875517; called by muse, mutect2, varscan2
- KRTAP6-3 | c.47A>G p.Y16C | Missense Mutation (SNP) | VAF 6/65 reads (9%) | PolyPhen benign (0.037); catalogued as COSV101196469; called by muse, mutect2
- LAMA2 | c.8998C>T p.H3000Y | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1417315374, COSV70344262; called by mutect2, varscan2
- LCP2 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV50448548; called by muse, mutect2
- LGI1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as COSV65057819; called by muse, varscan2
- LILRB5 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as COSV60256405; called by muse, mutect2, varscan2
- LIN28B | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61493966; called by muse, mutect2, varscan2
- LMO7 | c.2243G>A p.R748K (on ENST00000357063; = p.R429K on NM_005358.5) | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58533281, COSV58533864; called by mutect2, varscan2
- LMOD1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV66172235; called by mutect2, varscan2
- LNX1 | c.539A>C p.D180A (on ENST00000263925 / NM_001126328.3; = p.D84A on NM_032622.2) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.114); catalogued as COSV55784168; called by muse, mutect2, varscan2
- LPAR4 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.017); catalogued as rs1179974139, COSV70912441; called by mutect2, varscan2
- LRIT1 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64512309; called by muse, mutect2, varscan2
- LRP2 | c.3487G>A p.D1163N | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.811); catalogued as COSV55548744; called by muse, mutect2, varscan2
- LRRC10 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs751473904, COSV64060089; called by mutect2, varscan2
- LRRC8D | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100487478, COSV61578505; called by muse, mutect2, varscan2
- LSG1 | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 26/103 reads (25%) | catalogued as rs891363347, COSV99503013; called by muse, mutect2, varscan2
- MAGEB6B | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.143); catalogued as rs1422177813; called by muse, mutect2, varscan2
- MAN1A1 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV63782072; called by muse, mutect2
- MAN1A1 | c.621G>A p.W207* | Nonsense Mutation (SNP) | VAF 13/122 reads (11%) | catalogued as COSV63782078; called by muse, mutect2
- MAP10 | c.1709G>A p.R570K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as COSV69363332; called by muse, mutect2
- MAP3K9 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757467747, COSV67120797; called by mutect2, varscan2
- MAPK8IP3 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51718771; called by muse, mutect2, varscan2
- MARVELD2 | c.815T>C p.V272A | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as COSV57780235; called by muse, mutect2, varscan2
- MCL1 | c.635C>T p.T212I | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs1343989419, COSV57190171; called by muse, mutect2, varscan2
- MDC1 | c.6079C>T p.P2027S | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as rs754632799, COSV64524104; called by muse, mutect2, varscan2
- MECOM | c.2543G>A p.R848Q (on ENST00000468789 / NM_001105078.4; = p.R1036Q on NM_004991.4) | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs756700169, COSV52959825, COSV52966120; called by mutect2, varscan2
- METTL21C | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.59); catalogued as rs867270638, COSV99939965; called by mutect2, varscan2
- METTL21C | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.59); catalogued as COSV99939967; called by muse, mutect2, varscan2
- MFSD5 | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | catalogued as COSV61565313, COSV61565376; called by mutect2, varscan2
- MLXIPL | c.1867C>T p.P623S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV57667710; called by muse, mutect2, varscan2
- MMP25 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as COSV60679120; called by muse, mutect2, varscan2
- MMP3 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs782821084, COSV55405152; called by mutect2, varscan2
- MPP7 | c.1299-1G>A p.X433_splice | Splice Site (SNP) | VAF 13/130 reads (10%) | catalogued as COSV61731342; called by muse, mutect2, varscan2
- MROH2B | c.4429G>A p.D1477N | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.234); catalogued as COSV68180970; called by muse, mutect2, varscan2
- MS4A2 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as rs766717343, COSV54011564, COSV54011786; called by muse, mutect2, varscan2
- MTMR7 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs781567821, COSV51663614; called by mutect2, varscan2
- MTRR | c.1417C>T p.P473S (on ENST00000264668; = p.P446S on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52942749; called by muse, mutect2
- MTUS2 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV70915698; called by mutect2, varscan2
- MUC16 | c.21725C>T p.S7242F | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV67458459, COSV67472760; called by muse, mutect2, varscan2
- MUC16 | c.20927C>T p.P6976L | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as rs755758077, COSV67458471, COSV67470075; called by muse, mutect2, varscan2
- MUC17 | c.11162C>T p.T3721I | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60285444; called by muse, mutect2, varscan2
- MXRA5 | c.3013C>T p.P1005S | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV54225663, COSV99479209; called by muse, mutect2, varscan2
- MYH15 | c.3688G>A p.E1230K | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56307843; called by muse, mutect2
- MYH4 | c.4880A>T p.N1627I | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55116018; called by muse, mutect2, varscan2
- MYH4 | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1468834018, COSV55116034; called by muse, mutect2
- MYH8 | c.3406G>A p.E1136K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67963057; called by muse, mutect2
- MYOM3 | c.710G>A p.G237D | Missense Mutation (SNP) | VAF 55/313 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58390186; called by muse, mutect2, varscan2
- NCOA6 | c.3593C>T p.P1198L | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV62862691; called by muse, mutect2, varscan2
- NDST3 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56616710; called by muse, mutect2, varscan2
- NIBAN1 | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.088); catalogued as COSV62284224; called by muse, varscan2
- NLRP2 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54753915; called by muse, mutect2, varscan2
- NLRP9 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV60461861, COSV60466347; called by muse, mutect2, varscan2
- NPIPB15 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs1360859344, COSV70437102; called by muse, mutect2
- NPR1 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV64117462; called by muse, mutect2, varscan2
- NRG1 | c.1409C>T p.P470L (on ENST00000405005 / NM_013964.5; = p.P475L on NM_013956.5) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.47); PolyPhen probably damaging (1); catalogued as rs775055294, COSV55154171; called by muse, mutect2, varscan2
- NRG3 | c.1158G>A p.K386= | Splice Region (SNP) | VAF 14/53 reads (26%) | catalogued as rs267602593, COSV64548620; called by muse, mutect2, varscan2
- NRK | c.3424G>A p.D1142N | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV54593428; called by muse, varscan2
- NUP133 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54569901; called by muse, mutect2
- NUP153 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV50447981; called by muse, mutect2, varscan2
- OR10H3 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.434); catalogued as rs770494327, COSV59943650; called by muse, mutect2, varscan2
- OR1N2 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65460476; called by muse, mutect2, varscan2
- OR1S1 | c.487T>C p.F163L | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV58706716; called by muse, mutect2, varscan2
- OR2G2 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60740102; called by muse, mutect2, varscan2
- OR2M7 | c.684G>A p.M228I | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV58738609; called by muse, mutect2
- OR4N5 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs945355491, COSV61320366; called by muse, mutect2
- OR51E1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67809659, COSV67810917; called by muse, mutect2, varscan2
- OR5K1 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs199803370, COSV100221046; called by muse, mutect2, varscan2
- OR5R1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV56571971; called by muse, mutect2, varscan2
- OR6C75 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV58551180; called by muse, mutect2, varscan2
- OR6F1 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV57467456, COSV57468333; called by muse, varscan2
- OR7G2 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs1425976724, COSV59687702; called by muse, mutect2
- OR8B8 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV60143728; called by mutect2, varscan2
- ORC3 | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 9/68 reads (13%) | catalogued as COSV57639654; called by muse, mutect2, varscan2
- OSBPL11 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.236); catalogued as COSV56173499; called by muse, mutect2
- OTX2 | c.307G>A p.G103R (on ENST00000408990 / NM_172337.3; = p.G111R on NM_021728.4) | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV59765220, COSV59765817; called by muse, mutect2
- PAPPA2 | c.3557G>A p.G1186E | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.882); catalogued as COSV62794727; called by muse, varscan2
- PARM1 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.082); catalogued as COSV56652092; called by muse, mutect2
- PAX1 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.741); catalogued as COSV68271544; called by muse, mutect2, varscan2
- PCDH11Y | c.625G>A p.E209K (on ENST00000400457 / NM_032973.2; = p.E198K on NM_032971.3) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV53072701; called by mutect2, varscan2
- PCDHA10 | c.890G>A p.R297K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as COSV56479706; called by muse, mutect2, varscan2
- PCDHB10 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.014); catalogued as COSV53377514; called by muse, mutect2, varscan2
- PCDHB6 | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50693564; called by muse, mutect2, varscan2
- PCDHGB1 | c.692A>C p.D231A | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53927594; called by muse, mutect2
- PCLO | c.13940G>A p.G4647E | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); catalogued as COSV61626986; called by muse, mutect2, varscan2
- PCLO | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.085); catalogued as COSV61620963; called by muse, mutect2
- PDILT | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.121); catalogued as COSV56701010; called by muse, mutect2, varscan2
- PDZD2 | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as COSV56855660; called by muse, mutect2, varscan2
- PHC3 | c.1523C>T p.S508F (on ENST00000494943 / NM_001308116.2; = p.S520F on NM_024947.4) | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV71948548; called by muse, mutect2, varscan2
- PIP5K1B | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV55245516; called by muse, mutect2, varscan2
- PKHD1L1 | c.7894C>T p.P2632S | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65740889; called by muse, mutect2
- PKP2 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs796827562, COSV50730648; called by mutect2, varscan2
- PLCE1 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV53345585; called by muse, mutect2, varscan2
- PLG | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51982056; called by muse, mutect2
- PLXNB2 | c.4342C>T p.L1448F | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376965540, COSV63780953; called by muse, mutect2, varscan2
- PLXND1 | c.3967C>T p.R1323C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60711669; called by muse, mutect2, varscan2
- PLXND1 | c.1772C>T p.T591I | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as COSV60711917; called by muse, mutect2, varscan2
- PMS1 | c.2683G>A p.E895K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV59715752; called by muse, mutect2, varscan2
- PPARGC1A | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53526485; called by muse, mutect2
- PREX2 | c.2041C>T p.P681S | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55762390; called by muse, mutect2, varscan2
- PRKCQ | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54109454; called by muse, mutect2, varscan2
- PROKR2 | c.20A>G p.N7S | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV54085905; called by muse, mutect2
- PSG2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 30/357 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as rs376432612; called by muse, mutect2
- PSG4 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 51/410 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.395); catalogued as COSV54934902; called by muse, varscan2
- PTGER3 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV100656398, COSV100656836; called by muse, mutect2, varscan2
- PTPRD | c.3304A>C p.K1102Q | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.459); catalogued as COSV61937929; called by mutect2, varscan2
- PTPRE | c.1551G>A p.W517* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | catalogued as COSV54549280; called by muse, mutect2, varscan2
- PTPRE | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.175); catalogued as COSV54549298; called by muse, mutect2, varscan2
- PTPRK | c.4145G>A p.R1382Q (on ENST00000368215 / NM_001291984.2; = p.R1383Q on NM_002844.4) | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1239642954, COSV63892039; called by muse, mutect2, varscan2
- RALGAPA2 | c.4769G>A p.G1590E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52493997; called by muse, mutect2
- RASAL3 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV59139730; called by muse, varscan2
- RASGRF1 | c.1424C>T p.T475I | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as rs776185467, COSV69177225; called by mutect2, varscan2
- RASSF6 | c.892C>T p.R298C (on ENST00000342081 / NM_201431.2; = p.R266C on NM_177532.5) | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs754072709, COSV56717516; called by muse, mutect2, varscan2
- RBM28 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV56162631; called by muse, mutect2, varscan2
- RLN3 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780646663, COSV54600074; called by mutect2, varscan2
- RP1 | c.2779C>T p.P927S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as rs1225721620, COSV55114244; called by muse, mutect2
- RP1 | c.3520G>A p.E1174K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55114254; called by muse, mutect2
- RP1 | c.3626C>T p.S1209F | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV55114268; called by muse, mutect2, varscan2
- RP1 | c.3919G>A p.D1307N | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV55114278; called by mutect2, varscan2
- RP1 | c.4361G>A p.S1454N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV55114288; called by mutect2, varscan2
- RPRD2 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 32/391 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs376972465; called by muse, mutect2
- RXFP1 | c.1649A>G p.K550R | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV57048626; called by muse, mutect2, varscan2
- SALL3 | c.3025C>T p.L1009F | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs1429595608, COSV73305939; called by muse, mutect2, varscan2
- SCN5A | c.5615A>G p.K1872R (on ENST00000333535 / NM_198056.3; = p.K1871R on NM_000335.5) | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.196); catalogued as COSV61121006; called by muse, mutect2
- SEC61A1 | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV54576728; called by mutect2, varscan2
- SEMA6C | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59006567, COSV59007051, COSV59007588; called by muse, mutect2
- SESN2 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV53427260; called by muse, mutect2, varscan2
- SGMS1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62370051; called by muse, varscan2
- SHANK2 | c.3382G>A p.E1128K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs1555153976, COSV53593387; called by muse, mutect2, varscan2
- SIGLECL1 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV57062596; called by muse, mutect2
- SIRPB1 | c.548G>A p.W183* | Nonsense Mutation (SNP) | VAF 14/127 reads (11%) | catalogued as COSV53538197; called by muse, varscan2
- SLC26A9 | c.123C>T p.F41= | Splice Region (SNP) | VAF 27/248 reads (11%) | catalogued as rs1558129165, COSV61601987; called by mutect2, varscan2
- SLCO1B3 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs1349111961, COSV53935552; called by muse, mutect2, varscan2
- SLCO6A1 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 25/252 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV65808387, COSV65808697; called by muse, mutect2, varscan2
- SNED1 | c.1937C>T p.P646L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV60022023; called by muse, mutect2, varscan2
- SORCS1 | c.1708G>A p.V570I | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV53856056; called by mutect2, varscan2
- SPEG | c.8444C>T p.P2815L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs201240253, COSV56666622; called by mutect2, varscan2
- SPNS1 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV57954265; called by muse, mutect2, varscan2
- SPRR2A | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66991285; called by muse, mutect2, varscan2
- SSX3 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV53643788; called by muse, mutect2, varscan2
- ST18 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV52490268; called by muse, mutect2, varscan2
- STARD6 | c.408A>T p.E136D | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV57141896; called by muse, mutect2, varscan2
- SVEP1 | c.7811C>T p.S2604F | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs757218433, COSV52836341; called by muse, mutect2, varscan2
- SYNE2 | c.2379G>A p.M793I | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV59946472; called by muse, mutect2, varscan2
- SYTL2 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV60355683, COSV60364905; called by muse, mutect2, varscan2
- TAF7 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.114); catalogued as COSV57665079; called by muse, mutect2, varscan2
- TANC2 | c.5389C>T p.P1797S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.533); catalogued as rs1246120117, COSV67332995; called by mutect2, varscan2
- TAOK2 | c.3124C>T p.P1042S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV54229419; called by muse, mutect2, varscan2
- TAS1R2 | c.2332A>T p.T778S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64744367; called by muse, mutect2, varscan2
- TBX18 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs753516864, COSV63736561; called by mutect2, varscan2
- TCN1 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV57252822, COSV99953366; called by mutect2, varscan2
- TDRD1 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as rs1262278253, COSV52589512; called by muse, mutect2, varscan2
- TENM3 | c.2173G>A p.G725S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69304163; called by muse, mutect2, varscan2
- TET1 | c.4313C>T p.T1438I | Missense Mutation (SNP) | VAF 47/226 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1390003346, COSV65383736; called by mutect2, varscan2
- TEX15 | c.4003C>T p.P1335S (on ENST00000256246; = p.P1718S on NM_001350162.2) | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.511); catalogued as COSV56344739; called by muse, mutect2, varscan2
- THRSP | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.033); catalogued as COSV55246172; called by muse, varscan2
- THSD7B | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV55654466; called by mutect2, varscan2
- TLE4 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs866711978, COSV54629940; called by muse, varscan2
- TLL2 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.492); catalogued as COSV63571759; called by muse, mutect2, varscan2
- TLL2 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV63571763; called by muse, varscan2
- TLN2 | c.2182C>T p.P728S | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV60888143; called by muse, mutect2, varscan2
- TM6SF1 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV51943806; called by muse, mutect2
- TMEM17 | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59022607; called by muse, mutect2, varscan2
- TMEM266 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs762095902, COSV66378546; called by mutect2, varscan2
- TPO | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.155); catalogued as COSV61099321; called by muse, mutect2, varscan2
- TRIM65 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV53932758, COSV53934393; called by muse, mutect2, varscan2
- TTC31 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 27/272 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs368964545; called by muse, mutect2, varscan2
- TTLL6 | c.2401A>C p.N801H (on ENST00000393382 / NM_001130918.3; = p.N494H on NM_173623.3) | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV64976775, COSV64978617; called by muse, mutect2, varscan2
- TTN | c.65092G>A p.E21698K (on ENST00000591111; = p.E14274K on NM_003319.4) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | PolyPhen probably damaging (0.994); catalogued as COSV59983214; called by muse, mutect2, varscan2
- TTN | c.29161G>A p.V9721M (on ENST00000591111; = p.V8794M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/114 reads (9%) | PolyPhen probably damaging (0.935); catalogued as COSV59983264; called by muse, mutect2
- TTN | c.22894C>T p.P7632S (on ENST00000591111; = p.P6705S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/133 reads (11%) | PolyPhen benign (0.114); catalogued as COSV59983275, COSV60243908; called by muse, mutect2, varscan2
- TTN | c.1310G>A p.R437K | Missense Mutation (SNP) | VAF 24/152 reads (16%) | PolyPhen benign (0.359); catalogued as COSV100596175, COSV60261354; called by muse, mutect2, varscan2
- TUBA3C | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.518); catalogued as rs774052893, COSV68027856; called by muse, mutect2, varscan2
- UBE2L6 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.058); catalogued as rs868642148, COSV54702734; called by muse, mutect2
- UBQLN3 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV61163833; called by muse, mutect2
- ULK1 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100416526; called by muse, mutect2, varscan2
- ULK1 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs369296208; called by muse, mutect2, varscan2
- UNC13A | c.4129G>A p.E1377K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV53192642; called by muse, mutect2, varscan2
- USP42 | c.3808T>C p.F1270L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as COSV60359167; called by muse, mutect2, varscan2
- VN1R2 | c.705G>A p.W235* | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | catalogued as COSV59037821; called by muse, mutect2, varscan2
- VPS13B | c.11583G>C p.Q3861H | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62138496; called by muse, mutect2, varscan2
- VSIR | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99819077; called by mutect2, varscan2
- VSIR | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200507926, COSV99819078; called by mutect2, varscan2
- VSTM4 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60525593; called by muse, mutect2, varscan2
- WDR11 | c.191T>C p.V64A | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV54787244; called by muse, mutect2, varscan2
- WDR12 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 58/526 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs749587828, COSV53686940; called by muse, mutect2, varscan2
- WDR47 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 84/349 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs140178030; called by muse, mutect2, varscan2
- WNT8B | c.1024G>A p.G342S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs773154321, COSV59325002; called by mutect2, varscan2
- XCR1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as rs1318953736, COSV100499296; called by muse, mutect2, varscan2
- XDH | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV65148032; called by mutect2, varscan2
- XKR3 | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.154); catalogued as COSV58885422, COSV58885941; called by muse, mutect2
- XKR4 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59309600; called by muse, mutect2
- XPO5 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV54829153; called by mutect2, varscan2
- YEATS2 | c.3658C>T p.P1220S | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.355); catalogued as COSV59364109; called by muse, mutect2, varscan2
- YLPM1 | c.1828C>T p.L610F | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated, low confidence (0.49); PolyPhen possibly damaging (0.905); catalogued as COSV53109786; called by muse, mutect2, varscan2
- YTHDF1 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV64832772; called by muse, mutect2, varscan2
- ZBTB4 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.448); catalogued as COSV60978425; called by muse, mutect2, varscan2
- ZBTB5 | c.1972A>T p.K658* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as COSV57039656; called by mutect2, varscan2
- ZDHHC15 | c.446C>A p.A149D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64901259; called by muse, mutect2, varscan2
- ZDHHC23 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.706); catalogued as rs774620216, COSV57629241; called by muse, mutect2, varscan2
- ZIM3 | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV54141631; called by muse, mutect2, varscan2
- ZNF229 | c.1846C>T p.L616F | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.972); catalogued as COSV52161043; called by muse, mutect2
- ZNF229 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52161057; called by mutect2, varscan2
- ZNF234 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as COSV70603104; called by muse, mutect2
- ZNF385D | c.342G>A p.M114I | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1189602032, COSV55749213; called by mutect2, varscan2
- ZNF536 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as COSV62822076; called by muse, mutect2
- ZNF544 | c.626A>G p.D209G | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs776998159, COSV54135273; called by muse, varscan2
- ZNF570 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV57578725; called by muse, mutect2, varscan2
- ZNF586 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV66972252; called by muse, mutect2, varscan2
- ZNF649 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56814998; called by muse, mutect2, varscan2
- ZNF668 | c.1177C>T p.H393Y | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV56213142; called by muse, mutect2
- ZNF99 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV68055414, COSV68057004; called by muse, mutect2
- ZUP1 | c.85A>T p.I29F | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV63944213; called by muse, mutect2, varscan2
- DDX3X | c.887_893del p.P296Rfs*22 (on ENST00000399959; = p.P297Rfs*22 on NM_001356.5) | Frame Shift Del (DEL) | VAF 31/161 reads (19%) | called by mutect2, pindel, varscan2
- IGKV1D-8 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- KIR2DL4 | c.1142C>T p.S381F (on ENST00000396284; = p.S307F on NM_001080770.2) | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRAMEF14 | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.176); called by mutect2, varscan2
- PRAMEF14 | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.402); called by mutect2, varscan2
- PRAMEF15 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); called by mutect2, varscan2
- PRAMEF20 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 70/429 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRH2 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); called by muse, mutect2
- TRAV4 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.215); called by mutect2, varscan2
- A1CF | c.1083C>T p.F361= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV50960760; called by muse, mutect2, varscan2
- ABCC12 | c.471G>A p.G157= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV60913058; called by muse, mutect2, varscan2
- ACOXL | c.570G>A p.G190= | Silent (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- ADAM18 | c.1191T>C p.I397= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV55845935; called by muse, mutect2
- ADCY8 | c.522C>T p.F174= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs1439998118, COSV53895941, COSV53903391; called by muse, mutect2
- AGTR2 | c.975C>T p.F325= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV64156342; called by muse, mutect2, varscan2
- AMOT | c.1722C>T p.I574= (on ENST00000371959 / NM_001113490.1; = p.I165= on NM_133265.3) | Silent (SNP) | VAF 49/180 reads (27%) | catalogued as COSV59062355; called by muse, mutect2, varscan2
- ANKFN1 | c.546C>T p.I182= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV59444889; called by mutect2, varscan2
- ANKRD22 | c.528G>A p.R176= | Silent (SNP) | VAF 26/152 reads (17%) | catalogued as COSV64236267; called by muse, mutect2, varscan2
- ANKRD30A | c.1149C>T p.I383= (on ENST00000611781; = p.I327= on NM_052997.2) | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as rs868304038, COSV100653525, COSV64606919; called by muse, mutect2, varscan2
- APCS | c.321C>T p.F107= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs987625787, COSV54817777; called by muse, mutect2, varscan2
- ARHGAP39 | c.543G>A p.K181= | Silent (SNP) | VAF 18/218 reads (8%) | catalogued as COSV52768845; called by muse, mutect2
- ASAH2 | c.1512C>T p.I504= | Silent (SNP) | VAF 29/133 reads (22%) | called by muse, mutect2, varscan2
- ATP2B4 | c.2448C>T p.I816= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV58176368; called by mutect2, varscan2
- ATP8B4 | c.3102C>T p.S1034= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV52713135; called by muse, mutect2, varscan2
- BAIAP2L2 | c.342C>T p.F114= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV60201675; called by muse, mutect2, varscan2
- BICD1 | c.1896C>T p.I632= | Silent (SNP) | VAF 22/153 reads (14%) | catalogued as COSV55677493; called by muse, mutect2, varscan2
- BPIFB2 | c.1029C>T p.V343= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV50063889; called by muse, mutect2, varscan2
- BTBD7 | c.1389C>T p.I463= | Silent (SNP) | VAF 20/149 reads (13%) | catalogued as COSV58284846; called by muse, mutect2, varscan2
- BTNL9 | c.357G>A p.Q119= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV59795101; called by muse, mutect2, varscan2
- C4orf17 | c.802C>T p.L268= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV58511769; called by muse, mutect2, varscan2
- C6 | c.1965C>T p.I655= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV54705476, COSV54708392; called by mutect2, varscan2
- CACNA1E | c.4554C>T p.T1518= | Silent (SNP) | VAF 19/194 reads (10%) | catalogued as COSV62389391; called by muse, mutect2
- CCDC170 | c.489G>A p.K163= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs895490193, COSV53339425, COSV53342182; called by muse, mutect2, varscan2
- CCDC63 | c.1113C>T p.S371= | Silent (SNP) | VAF 15/147 reads (10%) | catalogued as COSV57528007, COSV57532202; called by muse, mutect2, varscan2
- CD84 | c.858G>A p.R286= (on ENST00000311224 / NM_001184879.2; = p.R269= on NM_003874.4) | Silent (SNP) | VAF 36/585 reads (6%) | catalogued as COSV60867619; called by muse, mutect2
- CEACAM8 | c.699C>T p.V233= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as COSV54990538; called by muse, mutect2, varscan2
- CEACAM8 | c.144G>A p.G48= | Silent (SNP) | VAF 20/167 reads (12%) | catalogued as COSV54990079, COSV99747869; called by muse, mutect2, varscan2
- CFTR | c.633C>T p.L211= | Silent (SNP) | VAF 19/222 reads (9%) | catalogued as COSV50046748; called by muse, mutect2
- CHRM3 | c.792G>A p.E264= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as COSV55086106; called by muse, mutect2, varscan2
- CIDEA | c.198C>T p.L66= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs1228440302, COSV57598030; called by muse, mutect2, varscan2
- CNTN2 | c.1636C>T p.L546= | Silent (SNP) | VAF 20/200 reads (10%) | catalogued as COSV59349416; called by muse, mutect2
- CR2 | c.450C>T p.F150= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV65507071; called by muse, mutect2, varscan2
- CRX | c.612C>T p.S204= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as rs750145677, COSV55757772; called by muse, mutect2, varscan2
- CSHL1 | c.225C>T p.F75= | Silent (SNP) | VAF 24/185 reads (13%) | catalogued as COSV51987709; called by muse, mutect2, varscan2
- CSTF2 | c.225G>A p.R75= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100802908; called by muse, mutect2, varscan2
- CXCR6 | c.213G>A p.V71= | Silent (SNP) | VAF 30/160 reads (19%) | catalogued as COSV56115180; called by mutect2, varscan2
- CYP4F12 | c.1179C>T p.P393= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV61173241; called by muse, mutect2, varscan2
- CYP4Z1 | c.897C>T p.F299= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV61964609, COSV61964902; called by muse, mutect2, varscan2
- DBX2 | c.909C>T p.I303= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV60337177; called by muse, mutect2, varscan2
- DIP2B | c.1398A>G p.K466= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV56581819; called by muse, mutect2, varscan2
- DMBT1 | c.7587C>T p.I2529= (on ENST00000338354 / NM_001377530.1; = p.I1772= on NM_004406.3) | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs754600183, COSV57540214; called by muse, mutect2, varscan2
- DNAH3 | c.1248G>A p.K416= | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as COSV99765182; called by muse, mutect2
- DNAH5 | c.13009C>T p.L4337= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as COSV54217227; called by muse, varscan2
- DNAH7 | c.11682G>A p.R3894= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV56759331; called by muse, mutect2, varscan2
- DNHD1 | c.135C>T p.F45= | Silent (SNP) | VAF 26/208 reads (13%) | catalogued as rs753212855, COSV54433328, COSV54439956; called by mutect2, varscan2
- DPEP1 | c.435C>T p.S145= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV55359782; called by muse, mutect2
- DRD5 | c.1302C>T p.F434= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs750699062, COSV58577544; called by mutect2, varscan2
- EMC8 | c.423C>T p.I141= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV53667379; called by muse, mutect2, varscan2
- ENPEP | c.423C>T p.I141= | Silent (SNP) | VAF 16/154 reads (10%) | catalogued as COSV54447885; called by mutect2, varscan2
- ERI3 | c.93C>T p.L31= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs1471986321, COSV64831019; called by muse, mutect2, varscan2
- EXOC3L1 | c.507G>A p.L169= | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as rs1316052386, COSV52045760; called by muse, mutect2, varscan2
- FAT3 | c.1602G>A p.L534= | Silent (SNP) | VAF 48/572 reads (8%) | catalogued as COSV53096893; called by muse, mutect2
- FBXW10 | c.2970G>A p.V990= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as COSV57059584; called by mutect2, varscan2
- FBXW4 | c.879C>T p.F293= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV100489428, COSV58707438; called by mutect2, varscan2
- FCER1A | c.600G>A p.E200= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV63666686; called by muse, mutect2
- FCHO1 | c.156G>A p.A52= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs148025294, COSV53181905; called by mutect2, varscan2
- FGD2 | c.1650C>T p.F550= | Silent (SNP) | VAF 15/138 reads (11%) | catalogued as rs200880382, COSV51463038; called by muse, varscan2
- FREM1 | c.1989G>A p.K663= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV66521536; called by muse, mutect2, varscan2
- GAL3ST1 | c.720G>A p.L240= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as COSV58892318; called by muse, mutect2
- GFRA1 | c.1215C>T p.S405= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV62604471, COSV62608579; called by muse, mutect2, varscan2
- GIMAP5 | c.534G>A p.R178= | Silent (SNP) | VAF 14/174 reads (8%) | catalogued as COSV57529870; called by muse, mutect2
- GLYAT | c.57G>A p.R19= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV53538625; called by muse, mutect2, varscan2
- GPR26 | c.867C>T p.S289= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as rs1420999713, COSV52933461; called by muse, varscan2
- GRIN3A | c.669C>T p.I223= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV62451650; called by mutect2, varscan2
- GSTA2 | c.399C>T p.F133= | Silent (SNP) | VAF 43/348 reads (12%) | catalogued as COSV72414845; called by muse, mutect2, varscan2
- GUCA2A | c.318C>T p.I106= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV63691302; called by muse, mutect2, varscan2
- HAUS6 | c.1347C>T p.T449= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV65839804; called by muse, mutect2
- HGD | c.1071C>T p.F357= | Silent (SNP) | VAF 14/196 reads (7%) | catalogued as COSV52196537; called by muse, mutect2
- HTR3E | c.210C>T p.F70= (on ENST00000415389 / NM_001256613.1; = p.F85= on NM_182589.2) | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as COSV58946402; called by mutect2, varscan2
- IBSP | c.282G>A p.S94= | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as rs1220138624, COSV56895271, COSV56896453; called by muse, mutect2, varscan2
- IFT80 | c.1404G>A p.L468= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV58446638; called by muse, mutect2
- IFT88 | c.372C>T p.P124= (on ENST00000319980 / NM_001318493.2; = p.P115= on NM_006531.5 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as rs772460683, COSV60672504; called by muse, mutect2, varscan2
- IGF2BP1 | c.966C>T p.N322= | Silent (SNP) | VAF 25/172 reads (15%) | catalogued as COSV99288286; called by muse, mutect2, varscan2
- IGFL2 | c.178C>T p.L60= (on ENST00000377693 / NM_001135113.2; = p.L71= on NM_001002915.2) | Silent (SNP) | VAF 35/345 reads (10%) | catalogued as COSV66616791; called by muse, mutect2, varscan2
- IL12RB1 | c.228C>T p.F76= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs868743304, COSV59096780; called by mutect2, varscan2
- IL36B | c.267G>A p.Q89= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV52085544; called by muse, mutect2, varscan2
- ILDR1 | c.1518G>A p.E506= (on ENST00000344209 / NM_001199799.2; = p.E462= on NM_175924.4) | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV56549340; called by muse, mutect2, varscan2
- INSRR | c.2904C>T p.V968= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV63872130; called by mutect2, varscan2
- IPO9 | c.1095C>T p.I365= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as rs781261432, COSV64233383; called by mutect2, varscan2
- IQCA1 | c.1509G>A p.V503= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as rs779849050, COSV99608684; called by mutect2, varscan2
- KATNB1 | c.459C>T p.L153= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as COSV65560033; called by muse, mutect2, varscan2
- KCND2 | c.936C>T p.I312= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV58575688; called by muse, mutect2, varscan2
- KCNH6 | c.2145G>A p.R715= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV59002443; called by muse, mutect2, varscan2
- KDM2B | c.375C>T p.V125= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as rs1555316568, COSV65639532; called by muse, mutect2
- KIAA1958 | c.960G>A p.Q320= | Silent (SNP) | VAF 22/282 reads (8%) | catalogued as rs1220685901, COSV61722950; called by muse, mutect2
- KIF4B | c.2430G>A p.L810= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV70528786; called by muse, mutect2
- KRT5 | c.798C>T p.T266= | Silent (SNP) | VAF 16/202 reads (8%) | catalogued as COSV99357820; called by muse, mutect2
- KRTAP10-10 | c.687C>T p.L229= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as rs782180238, COSV59957727; called by muse, mutect2, varscan2
- KRTAP3-2 | c.99C>T p.P33= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as rs563405905, COSV101196010, COSV66957032; called by muse, mutect2, varscan2
- LILRA4 | c.420C>T p.T140= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV52491454; called by muse, mutect2
- LLGL2 | c.2136C>T p.F712= | Silent (SNP) | VAF 31/184 reads (17%) | catalogued as rs763958592, COSV51341888; called by muse, mutect2, varscan2
- LRP11 | c.909A>G p.T303= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV53333540; called by muse, mutect2, varscan2
- LRP2 | c.3801C>T p.V1267= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as COSV55548735, COSV99789360; called by muse, varscan2
- LRRN1 | c.1317C>T p.I439= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs771241048, COSV60013350; called by mutect2, varscan2
- LSG1 | c.1503C>T p.H501= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as COSV99503014; called by muse, mutect2, varscan2
- MAFA | c.900G>A p.V300= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100339212, COSV61087242; called by mutect2, varscan2
- MAGEA3 | c.813C>T p.F271= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as COSV64755961; called by muse, mutect2, varscan2
- MAP9 | c.387C>T p.F129= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV60904317; called by muse, mutect2
- MARCO | c.195C>T p.V65= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV59053510; called by muse, mutect2, varscan2
- MEAK7 | c.628C>T p.L210= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs200184964, COSV59143794; called by muse, mutect2, varscan2
- MUC16 | c.4320G>A p.G1440= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV67458489; called by muse, mutect2, varscan2
- MUC16 | c.2217G>A p.A739= | Silent (SNP) | VAF 22/151 reads (15%) | catalogued as rs756693651, COSV67458498; called by muse, mutect2, varscan2
- MUC21 | c.1446C>T p.L482= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV66220566, COSV66220846; called by mutect2, varscan2
- MXRA5 | c.1561C>T p.L521= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV54231258; called by muse, mutect2, varscan2
- MYH13 | c.5436G>A p.G1812= | Silent (SNP) | VAF 22/314 reads (7%) | catalogued as rs1473727024, COSV52824010; called by muse, mutect2
- MYH7B | c.501C>T p.P167= | Silent (SNP) | VAF 24/268 reads (9%) | catalogued as COSV53418389; called by muse, mutect2
- MYH8 | c.2658G>A p.E886= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV67963060; called by muse, mutect2, varscan2
- MYH8 | c.1032C>T p.F344= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs369506465; called by mutect2, varscan2
- MYOCD | c.1902C>T p.S634= | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as rs1302131108, COSV58501379, COSV58503674; called by muse, mutect2, varscan2
- NAALADL2 | c.1422C>T p.I474= | Silent (SNP) | VAF 49/205 reads (24%) | catalogued as rs759667216, COSV69155113; called by muse, mutect2, varscan2
- NALCN | c.4638G>A p.K1546= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV51928142; called by mutect2, varscan2
- NKAPL | c.429C>T p.F143= | Silent (SNP) | VAF 24/264 reads (9%) | catalogued as COSV59197478; called by muse, mutect2
- NLRC5 | c.5127C>T p.A1709= | Silent (SNP) | VAF 12/172 reads (7%) | catalogued as COSV52653203; called by muse, mutect2
- NLRP13 | c.1086G>A p.T362= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as rs773534045, COSV61621112; called by mutect2, varscan2
- NSUN4 | c.189C>T p.I63= | Silent (SNP) | VAF 51/169 reads (30%) | catalogued as COSV61062904; called by muse, mutect2, varscan2
- NUP205 | c.435C>T p.S145= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV53657471; called by muse, mutect2
- NYAP2 | c.36G>A p.E12= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV56002420; called by muse, mutect2
- ODAPH | c.348C>T p.F116= | Silent (SNP) | VAF 22/281 reads (8%) | catalogued as COSV61141050; called by muse, mutect2
- ODF4 | c.81G>A p.R27= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV60271938; called by muse, mutect2, varscan2
- OR10X1 | c.729G>A p.R243= | Silent (SNP) | VAF 35/137 reads (26%) | catalogued as COSV63767233; called by muse, mutect2, varscan2
- OR2G2 | c.652C>T p.L218= | Silent (SNP) | VAF 7/128 reads (5%) | catalogued as COSV60740110; called by muse, mutect2
- OR2M4 | c.222C>T p.I74= | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as COSV60707814; called by muse, mutect2
- OR2S2 | c.609G>A p.T203= | Silent (SNP) | VAF 16/119 reads (13%) | catalogued as rs377240592; called by muse, mutect2, varscan2
- OR2T1 | c.663G>A p.L221= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV63541653; called by muse, mutect2, varscan2
- OR2T4 | c.132C>T p.F44= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100822394; called by mutect2, varscan2
- OR2T4 | c.435C>T p.F145= | Silent (SNP) | VAF 24/160 reads (15%) | catalogued as rs1313221663, COSV63543478, COSV63543719; called by muse, mutect2, varscan2
- OR4C3 | c.558C>T p.A186= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV60585038, COSV60591168; called by muse, mutect2, varscan2
- OR4Q3 | c.231C>T p.F77= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as COSV59178100, COSV59179076; called by mutect2, varscan2
- OR5AK2 | c.639C>T p.V213= | Silent (SNP) | VAF 17/152 reads (11%) | catalogued as rs746780389, COSV58804271; called by mutect2, varscan2
- OR7C2 | c.42C>T p.L14= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV50180394; called by mutect2, varscan2
- OR8B3 | c.309C>T p.F103= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV63541562; called by muse, mutect2, varscan2
- OR9A4 | c.135C>T p.I45= | Silent (SNP) | VAF 27/191 reads (14%) | catalogued as COSV71885276, COSV71885390; called by muse, mutect2, varscan2
- OR9Q1 | c.876G>A p.R292= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV59039006; called by muse, mutect2, varscan2
- PCDHA4 | c.591G>A p.R197= | Silent (SNP) | VAF 11/120 reads (9%) | catalogued as COSV63540404; called by muse, mutect2
- PDE1B | c.1227C>T p.L409= | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as COSV54491823, COSV54495294; called by muse, varscan2
- PDGFRA | c.1518C>T p.L506= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV57266929; called by muse, mutect2, varscan2
- PER2 | c.2028C>T p.I676= | Silent (SNP) | VAF 18/144 reads (13%) | catalogued as rs200422765, COSV54522721; called by mutect2, varscan2
- PHLDB2 | c.1626A>G p.E542= | Silent (SNP) | VAF 31/155 reads (20%) | catalogued as rs759751318, COSV67310043; called by muse, mutect2, varscan2
- PHLDB2 | c.3126G>A p.L1042= (on ENST00000393925 / NM_001134439.2; = p.L999= on NM_145753.2) | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV67310054; called by muse, mutect2, varscan2
- PHLPP2 | c.3318G>A p.L1106= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV62423829; called by muse, mutect2, varscan2
- PIP4P2 | c.348C>T p.C116= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs1313015468, COSV53438210; called by mutect2, varscan2
- PITPNM2 | c.1332C>T p.S444= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as rs774473740, COSV54898995; called by mutect2, varscan2
- PKP2 | c.300C>T p.G100= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as COSV99297259; called by muse, mutect2, varscan2
- PLPPR1 | c.303C>A p.S101= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV66450533, COSV66452164; called by mutect2, varscan2
- PLXND1 | c.1773C>T p.T591= | Silent (SNP) | VAF 35/174 reads (20%) | catalogued as rs776752650, COSV100139105; called by muse, mutect2, varscan2
- POF1B | c.411G>A p.R137= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV53132651; called by muse, mutect2, varscan2
- POLR1A | c.5001C>T p.S1667= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as COSV55691617; called by muse, mutect2, varscan2
- POMT2 | c.1650C>T p.I550= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV55070545; called by muse, mutect2
- POTEF | c.3171C>T p.I1057= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV62540684; called by mutect2, varscan2
- POTEF | c.207C>T p.F69= | Silent (SNP) | VAF 28/274 reads (10%) | catalogued as COSV62540687, COSV62541251; called by muse, mutect2
- PRAMEF1 | c.777C>T p.F259= | Silent (SNP) | VAF 52/254 reads (20%) | catalogued as COSV60008081; called by muse, mutect2, varscan2
- PRAMEF14 | c.138G>A p.R46= | Silent (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- PRDM9 | c.894G>A p.G298= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as COSV57003928; called by muse, mutect2, varscan2
- PSG5 | c.624G>A p.T208= | Silent (SNP) | VAF 25/230 reads (11%) | catalogued as rs779008783, COSV61653986; called by muse, mutect2, varscan2
- RARB | c.987C>G p.L329= (on ENST00000383772 / NM_001290216.2; = p.L322= on NM_000965.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs114613844, COSV51970689; called by muse, mutect2, varscan2
- ROPN1B | c.42G>A p.L14= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV52541995; called by mutect2, varscan2
- RSPH6A | c.1401C>T p.V467= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV55571111; called by mutect2, varscan2
- RYR2 | c.5826C>T p.F1942= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV63677449; called by muse, mutect2, varscan2
- SAMD7 | c.252C>T p.A84= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV59418064; called by muse, mutect2
- SCN11A | c.1836G>A p.G612= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV56568449; called by muse, mutect2, varscan2
- SCUBE2 | c.2134C>T p.L712= (on ENST00000649792 / NM_001367977.2; = p.L557= on NM_001170690.2) | Silent (SNP) | VAF 29/229 reads (13%) | catalogued as COSV100496346; called by muse, mutect2, varscan2
- SELENBP1 | c.381C>T p.I127= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV64373262; called by muse, mutect2, varscan2
- SERPINA7 | c.355C>T p.L119= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV59665427; called by muse, mutect2, varscan2
- SERPINA7 | c.168G>A p.R56= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs752808913, COSV59665437; called by mutect2, varscan2
- SERPINI2 | c.831G>A p.E277= | Silent (SNP) | VAF 30/148 reads (20%) | catalogued as COSV52985466; called by muse, mutect2, varscan2
- SERPINI2 | c.579C>T p.F193= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs1378784214, COSV52985475; called by mutect2, varscan2
- SI | c.5170C>T p.L1724= | Silent (SNP) | VAF 10/172 reads (6%) | catalogued as COSV52273160; called by muse, mutect2
- SIGLEC1 | c.1122C>T p.T374= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as rs1215910907, COSV52461630; called by muse, mutect2, varscan2
- SLC26A9 | c.1458C>T p.V486= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as rs773803188, COSV61601976; called by mutect2, varscan2
- SLC30A3 | c.684G>A p.G228= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV51985003; called by muse, mutect2, varscan2
- SLC7A2 | c.204C>T p.I68= (on ENST00000494857 / NM_001370338.1; = p.I108= on NM_003046.6) | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs776545516, COSV50250541; called by mutect2, varscan2
- SLC8A1 | c.2166C>T p.F722= | Silent (SNP) | VAF 20/146 reads (14%) | catalogued as COSV100244682; called by mutect2, varscan2
- SLC8A3 | c.687C>T p.V229= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs1310607568, COSV63520336; called by mutect2, varscan2
- SNTG1 | c.1446C>T p.F482= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV52436246, COSV52475126; called by muse, mutect2, varscan2
- SORL1 | c.1806G>A p.S602= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as rs781728057, COSV52752370; called by mutect2, varscan2
- SRGAP3 | c.1581C>T p.I527= | Silent (SNP) | VAF 46/219 reads (21%) | catalogued as COSV64530498; called by muse, mutect2, varscan2
- STAB1 | c.5409C>T p.V1803= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs755216315, COSV58734527; called by mutect2, varscan2
- STAT3 | c.2049C>T p.F683= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as rs373256669, COSV52887121; called by mutect2, varscan2
- STK36 | c.3310C>T p.L1104= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV55325620; called by muse, mutect2, varscan2
- SUPT6H | c.4269C>T p.A1423= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV58926522; called by muse, varscan2
- SYT13 | c.681C>T p.L227= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as rs1328233084, COSV50073098; called by muse, mutect2, varscan2
- TAS2R38 | c.321C>T p.L107= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV71885277; called by muse, mutect2
- TCHH | c.252T>C p.A84= | Silent (SNP) | VAF 12/133 reads (9%) | catalogued as COSV64274022; called by muse, mutect2
- TENM1 | c.1096A>C p.R366= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV64429421; called by muse, mutect2, varscan2
- TFAP2B | c.801C>T p.L267= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs199498777; called by mutect2, varscan2
- TNFSF15 | c.414C>T p.F138= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as rs867957370, COSV65010140; called by muse, mutect2, varscan2
- TOMM40L | c.501C>T p.H167= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs200820654, COSV63467602; called by mutect2, varscan2
- TRAPPC9 | c.813C>T p.F271= | Silent (SNP) | VAF 21/142 reads (15%) | catalogued as rs138528079, COSV66896970; called by muse, mutect2, varscan2
- TRAV1-1 | c.135G>A p.G45= | Silent (SNP) | VAF 15/122 reads (12%) | called by muse, mutect2, varscan2
- TRPC4 | c.2499G>A p.Q833= (on ENST00000379705 / NM_016179.4; = p.Q838= on NM_003306.3) | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV58996699; called by muse, varscan2
- TRPM3 | c.456C>T p.S152= (on ENST00000357533 / NM_001366142.2; = p.S121= on NM_001007471.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV62469018; called by muse, mutect2, varscan2
- TSHR | c.384A>G p.L128= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs764752737, COSV53317921; called by muse, varscan2
- TTC14 | c.525C>T p.N175= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV56010542; called by muse, mutect2, varscan2
- UBQLN3 | c.1635C>T p.F545= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs866512375, COSV100293373; called by mutect2, varscan2
- UBQLN3 | c.598C>T p.L200= | Silent (SNP) | VAF 20/156 reads (13%) | catalogued as COSV100293378; called by muse, mutect2, varscan2
- ULK1 | c.2559C>T p.F853= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs139624236, COSV58858289; called by mutect2, varscan2
- UNC5D | c.867C>T p.A289= | Silent (SNP) | VAF 13/141 reads (9%) | catalogued as COSV54784108; called by muse, mutect2
- USH2A | c.12609G>A p.Q4203= | Silent (SNP) | VAF 20/170 reads (12%) | catalogued as COSV56353778; called by muse, varscan2
- VPS41 | c.1044C>T p.I348= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs772712776, COSV59647708, COSV59651777; called by mutect2, varscan2
- WFS1 | c.1734C>T p.A578= | Silent (SNP) | VAF 63/539 reads (12%) | catalogued as rs964981863, COSV56988434; called by muse, mutect2, varscan2
- XIRP1 | c.4722C>T p.F1574= | Silent (SNP) | VAF 19/195 reads (10%) | catalogued as COSV61137850; called by muse, mutect2, varscan2
- ZC3H12C | c.1017C>T p.I339= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1324541822, COSV53707790; called by mutect2, varscan2
- ZNF142 | c.2016C>T p.L672= (on ENST00000411696 / NM_001379660.1; = p.L472= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as COSV68743419; called by muse, mutect2
- ZNF461 | c.1320C>T p.P440= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV64453390; called by muse, mutect2
- ZNF521 | c.2910C>T p.S970= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs1357529558, COSV64125163; called by muse, mutect2, varscan2
- ZNF536 | c.2742C>T p.F914= | Silent (SNP) | VAF 30/271 reads (11%) | catalogued as rs781726692, COSV62822080; called by muse, varscan2
- ZNF623 | c.927C>T p.H309= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV71697144; called by muse, mutect2, varscan2
- ZNF701 | c.786C>T p.F262= (on ENST00000301093; = p.F196= on NM_018260.3) | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs746772806, COSV56524084; called by mutect2, varscan2
- ZNF835 | c.393C>T p.I131= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV73379354; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847873 G>A | 5'Flank (SNP) | VAF 31/106 reads (29%) | called by muse, mutect2, varscan2
- ANKRD33 | c.-116C>T | 5'UTR (SNP) | VAF 7/73 reads (10%) | catalogued as COSV56605559; called by muse, mutect2, varscan2
- C1QTNF7 | c.*2C>T | 3'UTR (SNP) | VAF 9/66 reads (14%) | catalogued as COSV99765026; called by muse, mutect2, varscan2
- CCNQP1 | n.634G>A | RNA (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2
- DCHS2 | n.5042G>A | RNA (SNP) | VAF 5/51 reads (10%) | catalogued as COSV61770118; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85381G>A | Intron (SNP) | VAF 6/44 reads (14%) | catalogued as COSV72276355; called by mutect2, varscan2
- MIR329-1 | n.73C>T | RNA (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- NBPF11 | c.-548-2922C>T | Intron (SNP) | VAF 15/91 reads (16%) | called by muse, mutect2, varscan2
- PLCB1 | c.2524-6194G>A | Intron (SNP) | VAF 6/42 reads (14%) | catalogued as rs1436147974; called by mutect2, varscan2
- PRR14L | chr22:31676970 G>A | 3'Flank (SNP) | VAF 6/44 reads (14%) | catalogued as rs1188321385; called by mutect2, varscan2
- RGS3 | c.3081-360C>T | Intron (SNP) | VAF 16/179 reads (9%) | catalogued as COSV100636565; called by muse, mutect2, varscan2
- SNORD52 | chr6:31839643 G>T | 3'Flank (SNP) | VAF 73/581 reads (13%) | catalogued as COSV63328660; called by muse, mutect2, varscan2
- WNK1 | c.2140-2233C>T | Intron (SNP) | VAF 53/452 reads (12%) | catalogued as COSV60029946; called by muse, mutect2, varscan2
